Gene-level copy-number profile of tumor specimen C3N-03457-02 from CPTAC case C3N-03457, project CPTAC-3 (Floor of mouth — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Floor of mouth, NOS; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 71.3 years (26,052 days).
Specimen C3N-03457-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Floor Of Mouth; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file ea5b0e1b-e84a-47b7-94f3-dc3480e07f32.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-03457-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,222 have no estimate.
https://portal.gdc.cancer.gov/files/c4987b59-6584-4a8c-bd58-60490bc63ffe

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 4; copy number 1: 12,757; copy number 2: 37,381; copy number 3: 5,036; copy number 4: 2,522; copy number 5: 210; copy number 6: 417; copy number 7: 8; copy number 8: 12; copy number 9: 3; copy number 11: 41; copy number 12: 10.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:114,613,787–114,613,906, 1 gene (within-gene range 0–2): RNA5SP238.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 429 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:77,793,728–81,770,438, 42 genes, copy number 5–6: TMEM60, PHTF2, Y_RNA, AC004990.1, MAGI2, AC004808.2, AC004808.1, RPL13AP17, AC006043.1, AC007237.1, MAGI2-AS1, MAGI2-AS2, RNU6-337P, AC006355.1, AC006355.2, AC074024.1, RNU6-530P, AC004945.1, MAGI2-AS3, NUP35P2, RNA5SP234, GNAI1, RNU6-849P, RPL10P11, RN7SL869P, AC003988.1, AC004862.1, RN7SL35P, CD36, SNRPBP1, GNAT3, AC073850.1, SEMA3C, AC004972.1, AC005008.2, AC005008.1, AC004866.1, AC004866.2, EIF4EP4, AC008163.1, DDX43P3, HGF.
- chr7:84,528,122–88,226,993, 36 genes, copy number 5–12 (within-gene range 4–12): RPL7P30, AC003984.1, AC093716.1, HMGN2P11, AC074183.2, AC074183.1, HNRNPA1P8, SEMA3D, HSPA8P16, DYNLL1P7, LINC00972, AC092013.1, SOCS5P1, GRM3, AC005009.1, GRM3-AS1, ELAPOR2, AC004023.1, AC005076.1, DMTF1, AC005076.2, TMEM243, Y_RNA, TP53TG1, AC005045.1, AC005045.2, CROT, ABCB4, ABCB1, HNRNPA1P9, RUNDC3B, SLC25A40, DBF4, ADAM22, SRI, SRI-AS1.
- chr8:39,522,976–40,172,612, 15 genes, copy number 5: AC123767.1, ADAM18, ADAM2, AP005902.2, AP005902.1, IDO1, AC007991.3, AC007991.2, AC007991.4, IDO2, AC007991.1, AC087518.1, LINC02866, TCIM, AC022733.1.
- chr11:68,870,664–72,139,892, 107 genes, copy number 5–11 (within-gene range 3–11) (broad region; genes not listed).
- chr13:62,397,645–62,397,916, 1 gene, copy number 8: AL356102.1.
- chr20:30,377,372–37,445,534, 228 genes, copy number 5–6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 12,757. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
